Gene-level copy-number profile of specimen HCM-BROD-0648-C71-85R from HCMI case HCM-BROD-0648-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.7 years (23,260 days).
Specimen HCM-BROD-0648-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 99c6c927-b1a2-4fa8-809e-209f6c364427.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0648-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/8600676c-3f0b-464d-888d-84a6ae9ee9f9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 4,680; copy number 2: 50,090; copy number 3: 3,976; copy number 4: 131; copy number 5: 6; copy number 19: 11.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:21,481,327–21,494,596, 2 genes (within-gene range 0–1): AC138951.1, AC138951.2.
- chr9:52,452–179,147, 6 genes: AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1.
- chr9:39,631,046–39,810,097, 7 genes: FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–2): BX664615.2.
- chr21:8,986,999–9,027,329, 4 genes: MIR3648-2, CR392039.1, CR392039.3, CDRT15P9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,218,853–204,562,521, 11 genes, copy number 19: PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr7:54,933,699–55,255,635, 5 genes, copy number 5: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr9:36,002,909–36,003,867, 1 gene, copy number 5: OR13C7.

Autosomal genes at a single copy (total copy number 1): 1,825. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
